Surgical pathology report (de-identified scan), TCGA case TCGA-20-1685, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-20-1685-01A (Primary Tumor).

[page 1 of 3]
TCGA-20-1685

Age:

Sex:

Clinical History/Diagnosis: Bilateral Ovarian Cyst

Source of Specimen(s):

- 1: Left Fallopian Tube and Ovary
- 2: Right Fallopian Tube and Ovary
- 3: Uterus and Cervix
- 4: Omentum
- 5: Pelvic Nodule
- 6: Ileum, Cecum, and Appendix

Gross Description:

Received in six parts.

Source of Tissue: 1. Labeled #1, "left tube and ovary"

Gross Description: Received fresh labeled " patient name and medical number, left tube and ovary". It consists of a large ovarian mass with attached fallopian tube weighing a total of 66 grams. The ovary measures 6.5 x 5.5 x 4.5 cm. The outer surface is gray-tan and rough with multiple scattered small papillary structures noted. The ovary is sectioned to reveal a partially cystic fleshy, firm cut surface. Attached fallopian tube is grossly distorted measuring 3 x 1.2 x 1 cm in greatest dimension. The fimbriated end is identified. The fallopian tube is grossly involved with the previously described ovarian mass. The tube is sectioned to reveal a small patent lumen with surrounding wall measuring up to 0.2 cm in thickness. Representative sections submitted in 1A-1D.

Designation of Sections: 1A-1B- random section of ovary, 1C-1D- fallopian tube with fimbriated end

Source of Tissue: 2. Labeled #2, "right tube and ovary"

Frozen Section Diagnosis: 2FS- PAPILLARY SEROUS.

Gross Description: Received fresh labeled " patient name and medical number, right tube and ovary". It consists of a fallopian tube with attached ovary weighing a total of 220 grams. The ovary measures 7.5 x 7.5 x 5.5 cm. The ovary is sectioned to reveal a fleshy, tan firm cut surface with one central cystic area noted measuring 4 cm in greatest dimension. The attached fallopian tube measures 2 x 1 x 1 cm. The outer surface is gray-tan and rough. The tube is sectioned to reveal a patent lumen with surrounding wall measuring up to 0.3 cm in thickness. Representative section of the ovary is frozen in 2FS. Additional sections of the remainder of the specimen are submitted in 2A-2E.

[page 2 of 3]
Designation of Sections: 2FS- frozen section, 2A-2D- random section of ovary, 2E- fallopian tube

Source of Tissue: 3. Labeled #3, "uterus and cervix"

Gross Description: Received fresh labeled " patient name and medical number, uterus and cervix". It consists of a uterus with attached cervix weighing a total of 119 grams. The cervix measures 4 cm in length and 3 cm in diameter. The ectocervical lining is tan-pink and smooth. The ectocervical os is slit-like, grossly patent measuring 0.6 cm in diameter. The cervix is sectioned to reveal a soft tan-pink cut surface with multiple scattered fluid filled Nabothian cysts present, the largest measuring 0.3 cm in diameter. The uterus measures 6.5 x 6 x 4.7 cm. The serosa is tan-pink, rough with multiple small scattered nodules present, the largest measuring 0.5 cm in greatest dimension. The uterus is bisected to reveal a smooth tan-pink endometrium that measures up to 0.2 cm in thickness. The myometrium is tan-pink, trabecular measuring up to 3 cm in thickness.

Source of Tissue: 4. Labeled #4, "omentum"

Gross Description: Received fresh labeled " patient name and medical number, omentum". It consists of two segments of omentum measuring 33 x 15 x 4 cm in greatest dimension. The omentum is sectioned to reveal multiple firm white-tan well-circumscribed masses measuring from 0.1 up to 6 cm in greatest dimension. Representative sections submitted in 4A-4D.

Source of Tissue: 5. Labeled #5, "pelvic nodule"

Gross Description: Received fresh labeled " patient name and medical number, pelvic nodule". It consists of two soft to firm irregular tissue fragments measuring 3.5 x 3 x 1.5 cm. Representative sections submitted in 5A.

Source of Tissue: 6. Labeled #6, "ileum, cecum and appendix"

Gross Description: Received fresh labeled " patient name and medical number, ileum, cecum and appendix". It consists of a segment of large bowel with attached terminal ileum and appendix. The terminal ileum measures 11.5 cm in length and 6 cm in circumference. The serosa is tan-pink and smooth. The terminal ileum is opened to reveal a well-demarcated, firm submucosal mass measuring 2 x 2 x 0.7 cm and comes within 2.5 cm from the closest proximal ileal margin. The remaining small bowel mucosa is tan-pink, rough

[page 3 of 3]
with no other discrete masses present. The ileocecal valve is identified and appears grossly unremarkable. The segment of large bowel measures 8.5 cm in length and 7 cm in circumference. The serosa is tan-pink and smooth. The large bowel is opened to reveal a smooth tan-pink mucosal lining with no mucosal ulcerations or polyps present. The appendix measures 5.5 x 0.7 x 0.7 cm. The appendix is sectioned to reveal a light-brown, soft cut surface with no discrete masses present. Representative sections submitted in 6A-6E.

Designation of Sections: 6A- proximal ileal margin, 6B- distal colonic margin, 6C- submucosal mass from terminal ileum, 6D- ileocecal valve, 6E- appendix

Final Diagnosis:

1. Left fallopian tube and ovary, salpingo-oophorectomy:
- Serous adenocarcinoma, high grade of ovary involving surface and fallopian tube; at least 5.0 cm.
- Angiolymphatic invasion is not identified.
2. Right fallopian tube and ovary, salpingo-oophorectomy:
- Serous adenocarcinoma, high grade of ovary involving surface and fallopian tube; at least 6.0 cm.
- Angiolymphatic invasion is present.
3. Uterus and cervix, hysterectomy:
- Uterus with invasive serosal implants of high grade serous adenocarcinoma.
- Cervix, No tumor seen.
4. Omentum, omentectomy:
- Serous adenocarcinoma, up to 6.0 cm.
- One lymph node negative for carcinoma (0/1).
5. Pelvic nodule, excision:
- Serous adenocarcinoma, at least 1.5 cm.
6. Ileum, cecum and appendix, segmental resection:
- Serous adenocarcinoma infiltrating through serosa and muscularis propria causing mucosal ulceration in terminal ileum, 2.0 cm.
- Appendix with invasive serosal implants of serous adenocarcinoma.
- Proximal ileal resection margin possible for serosal implant of serous adenocarcinoma.

Source: NCI Genomic Data Commons file c97b76bf-d299-478b-bcb3-072de1a44f3f (TCGA-20-1685.09B7C163-7AD3-42A2-BC06-32BD55F80327.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).